Gene-level copy-number profile of tumor specimen TCGA-AX-A3GI-01A from TCGA case TCGA-AX-A3GI, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 66.8 years (24,388 days).
Specimen TCGA-AX-A3GI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.14b9dc67-a85e-4867-87a7-b0f153816e50.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AX-A3GI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cf25ce89-96c0-491c-b308-0ee5e690ebd9

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,847; copy number 2: 19,947; copy number 3: 15,904; copy number 4: 19,069; copy number 5: 846; copy number 6: 1,386; copy number 7: 196; copy number 8: 218; copy number 9: 103; copy number 10: 25; copy number 11: 24; copy number 12: 18; copy number 15: 103; copy number 16: 16; copy number 17: 21; copy number 19: 8; copy number 23: 14; copy number 24: 65.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AX-A3GI-01A-11D-A20R-01): tumor purity 0.98, ploidy 1.64, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 308 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:41,929,479–42,207,709, 8 genes, copy number 19: KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT.
- chr8:106,980,967–108,626,767, 18 genes, copy number 10–23: AP003789.1, AP000428.2, HMGB1P46, AP000428.1, ANGPT1, AC091010.1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2.
- chr8:127,578,473–130,443,674, 41 genes, copy number 9 (within-gene range 7–9): AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1.
- chr8:132,775,358–139,508,971, 67 genes, copy number 9–17 (within-gene range 9–19) (broad region; genes not listed).
- chr11:83,455,012–85,627,922, 1 gene, copy number 11 (within-gene range 5–11): DLG2.
- chr11:84,545,131–92,896,470, 165 genes, copy number 9–15 (within-gene range 8–15) (broad region; genes not listed).
- chr11:95,976,598–96,514,748, 8 genes, copy number 10 (within-gene range 8–10): MAML2, AP000779.1, MIR1260B, CCDC82, JRKL, JRKL-AS1, RNA5SP346, LINC02737.

Autosomal genes at a single copy (total copy number 1): 771. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
